Surgical pathology report (de-identified scan), TCGA case TCGA-AG-A00C, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AG-A00C-01A (Primary Tumor).

TCGA #

Sample ID #:

Diagnosis / Diagnoses:

Rectosigmoid amputation specimen under inclusion of an ulcerated, moderately differentiated adenocarcinoma of the colorectal type, located immediately above the dentate line and measuring a maximum of 7 cm in diameter, with infiltration of the perirectal fatty tissue and a regional lymph node metastasis. Minimum distance between the tumor and the circumferential resection margin, 0.6 cm. Tumor-free oral and aboral amputation margin. Tumor-free mesenteric resection margin.

Tumor stage pT3 pN1 (1/24) pMX; G2, L1, V0, locally R0

ICD-O-3

Adenocarcinoma, NOS 8140/3

Site: Rectum C20.9 for 3/31/11

Source: NCI Genomic Data Commons file a1fe2c29-4608-432b-b315-6086623f6c8d (TCGA-AG-A00C.80ECEEA7-3D74-4275-856F-11ABB6ED93BF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).